Gene-level copy-number profile of tumor specimen TCGA-13-2066-01A from TCGA case TCGA-13-2066, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 49.7 years (18,170 days).
Specimen TCGA-13-2066-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bdda429f-5053-4937-8488-19a21aa95048.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-2066-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate.
https://portal.gdc.cancer.gov/files/f5fcb892-366a-47ff-9088-636bed057ce2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 4,092; copy number 3: 9,941; copy number 4: 22,845; copy number 5: 10,071; copy number 6: 6,316; copy number 7: 4,450; copy number 8: 636; copy number 9: 426; copy number 10: 61; copy number 11: 132; copy number 12: 367; copy number 13: 150; copy number 14: 80; copy number 15: 43; copy number 16: 16; copy number 19: 15; copy number 20: 2; copy number 21: 4; copy number 22: 61; copy number 25: 27; copy number 26: 9; copy number 27: 19; copy number 28: 9; copy number 29: 35; copy number 35: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,458 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–150,720,895, 54 genes, copy number 11–12: FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P.
- chr2:38,814–2,331,664, 40 genes, copy number 9 (within-gene range 7–9): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1.
- chr2:75,455,994–75,569,722, 5 genes, copy number 13 (within-gene range 6–13): GAPDHP57, EVA1A, AC007099.2, AC007099.3, AC007099.1.
- chr2:75,799,974–77,593,319, 16 genes, copy number 16 (within-gene range 6–16): AC110614.1, SUCLA2P2, AC073091.1, AC073091.2, PNPP1, USP21P2, RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1.
- chr2:170,178,145–177,223,958, 145 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr2:177,229,191–177,229,506, 1 gene, copy number 9: DNAJC19P5.
- chr6:167,607–4,583,871, 103 genes, copy number 9–15 (within-gene range 8–15) (broad region; genes not listed).
- chr6:14,152,196–14,211,186, 1 gene, copy number 15 (within-gene range 4–15): AL133259.1.
- chr6:14,210,293–25,057,073, 145 genes, copy number 9–27 (within-gene range 9–34) (broad region; genes not listed).
- chr6:25,061,796–25,141,403, 2 genes, copy number 10: AL133268.4, AL133268.1.
- chr6:36,027,677–37,091,806, 35 genes, copy number 11 (within-gene range 3–11): MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1, BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2.
- chr6:49,692,358–50,637,205, 16 genes, copy number 13 (within-gene range 6–13): CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1.
- chr7:70,837,738–72,447,151, 9 genes, copy number 10–14 (within-gene range 8–14): AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75, CALN1, RNA5SP232, AC005011.1, ABCF2P2.
- chr7:75,996,338–77,425,444, 48 genes, copy number 9 (within-gene range 8–9): STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2, AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1.
- chr7:80,972,516–83,664,625, 20 genes, copy number 9: AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2.
- chr8:4,317,388–4,788,584, 4 genes, copy number 21: AC027251.1, AC010941.1, AC022068.1, PAICSP4.
- chr8:5,455,218–10,839,884, 192 genes, copy number 9–19 (within-gene range 8–19) (broad region; genes not listed).
- chr8:12,467,693–12,665,588, 1 gene, copy number 13 (within-gene range 8–13): AC068587.4.
- chr8:12,570,350–13,909,780, 34 genes, copy number 13: RPS3AP34, AC068587.2, AC068587.8, AC068587.6, RPS3AP35, AC068587.3, AC068587.7, AC068587.5, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1.
- chr8:15,417,215–16,567,490, 9 genes, copy number 28 (within-gene range 2–28): TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2.
- chr8:20,934,435–20,950,175, 2 genes, copy number 19: TMEM97P2, AC015468.3.
- chr8:121,380,137–121,994,185, 4 genes, copy number 10: RPL35AP19, HAS2, HAS2-AS1, LINC02855.
- chr10:5,549,637–5,842,132, 11 genes, copy number 9 (within-gene range 6–9): AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1.
- chr10:64,036,345–64,170,850, 2 genes, copy number 35: AC012558.1, DBF4P1.
- chr11:167,784–2,849,105, 149 genes, copy number 12 (within-gene range 5–12) (broad region; genes not listed).
- chr11:9,778,667–11,243,715, 30 genes, copy number 9–13 (within-gene range 8–13): SBF2, AC011092.2, RNU7-28P, AC011092.1, AC011092.3, AC100763.1, AC080023.2, AC080023.1, ADM, AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1, IRAG1, Y_RNA, CTR9, EIF4G2, SNORD97, AC116535.1, ZBED5, ZBED5-AS1, AC069360.1, LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1.
- chr11:33,161,657–36,697,867, 73 genes, copy number 14–22 (broad region; genes not listed).
- chr12:24,566,964–27,161,393, 61 genes, copy number 13–25 (within-gene range 6–25) (broad region; genes not listed).
- chr12:28,978,584–31,652,095, 58 genes, copy number 12 (within-gene range 3–12): AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1.
- chr13:22,803,145–22,803,648, 2 genes, copy number 9: SNORD36, RPL7AP73.
- chr19:29,083,094–34,066,283, 103 genes, copy number 11–29 (within-gene range 7–29) (broad region; genes not listed).
- chr22:29,432,944–30,440,318, 47 genes, copy number 13: RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2.
- chr22:35,119,824–35,231,056, 1 gene, copy number 22 (within-gene range 6–22): LINC01399.
- chr22:35,164,304–36,204,840, 35 genes, copy number 22 (within-gene range 2–22): Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
